Somatic mutation profile of tumor specimen ALCH-B0BL-TTP1-A (aliquot ALCH-B0BL-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0BL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.2 years (21,637 days).
Specimen ALCH-B0BL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a946371-4278-499b-b54f-0e0ff51021f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0BL-NB1-A (Blood Derived Normal), aliquot ALCH-B0BL-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fe0a108-3e59-43fc-85aa-15305ee4d3a3

The open-access MAF lists 60 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, Frame Shift Del 3, 3'UTR 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Ins 2, Intron 2, RNA 1, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 858/1613 reads (53%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 44/243 reads (18%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD62 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1341792065, COSV58410956; called by muse, mutect2
- EPB41L1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 68/769 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52445995; called by muse, mutect2
- GRM1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 124/837 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs755116876, COSV51120943; called by muse, mutect2, varscan2
- HEATR1 | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100857765; called by muse, mutect2
- NCCRP1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1013503239; called by muse, mutect2
- RTTN | c.3787C>T p.L1263F | Missense Mutation (SNP) | VAF 70/742 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs769785834; called by muse, mutect2
- SPG11 | c.2340T>A p.N780K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55995179; called by muse, mutect2
- SYNE4 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV61011024; called by muse, varscan2
- TNXB | c.9940A>G p.T3314A (on ENST00000647633; = p.T3067A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as rs1198769077, COSV64477791; called by muse, mutect2
- ZNF229 | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs754516445, COSV52159418; called by muse, mutect2
- CD163L1 | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2
- CPO | c.882_907del p.R295Sfs*7 | Frame Shift Del (DEL) | VAF 64/400 reads (16%) | called by mutect2, pindel
- CRTAC1 | c.924_928del p.V309Wfs*44 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel, varscan2
- DCHS1 | c.5606C>G p.P1869R | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DDIT4L | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- EXOC3L4 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- FERMT1 | c.1238A>C p.E413A | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GABARAP | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK2 | c.3346A>G p.T1116A | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KNG1 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LRRC7 | c.791T>C p.I264T (on ENST00000651989 / NM_001370785.2; = p.I231T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2
- LSS | c.1999A>T p.I667F | Missense Mutation (SNP) | VAF 18/387 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- MED14 | c.4316_4320del p.V1439Gfs*5 | Frame Shift Del (DEL) | VAF 27/186 reads (15%) | called by mutect2, pindel, varscan2
- MYO15A | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- NUFIP2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 14/371 reads (4%) | called by muse, mutect2
- PHLDB1 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLXNA2 | c.4123C>T p.Q1375* | Nonsense Mutation (SNP) | VAF 50/563 reads (9%) | called by muse, mutect2
- POLR3E | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.059); called by muse, mutect2
- POTEE | c.2621C>G p.A874G | Missense Mutation (SNP) | VAF 159/1018 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, varscan2
- PRRC2B | c.5269dup p.A1757Gfs*13 | Frame Shift Ins (INS) | VAF 64/301 reads (21%) | called by mutect2, pindel, varscan2
- RBP7 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, varscan2
- SYNE2 | c.8669G>T p.G2890V | Missense Mutation (SNP) | VAF 63/437 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEKT3 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 372/1075 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM8 | c.191+1G>C p.X64_splice | Splice Site (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- TTLL12 | c.1478T>A p.L493Q | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF618 | c.2795T>G p.I932S (on ENST00000374126 / NM_001318042.2; = p.I839S on NM_133374.2) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.444); called by muse, mutect2
- ARHGAP44 | c.1899C>T p.S633= | Silent (SNP) | VAF 35/240 reads (15%) | called by muse, varscan2
- C19orf47 | c.898C>A p.R300= | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- DUSP6 | c.447C>G p.T149= | Silent (SNP) | VAF 53/261 reads (20%) | called by muse, mutect2, varscan2
- GPHN | c.1665C>G p.L555= (on ENST00000315266 / NM_001377519.1; = p.L588= on NM_020806.5) | Silent (SNP) | VAF 41/722 reads (6%) | called by muse, mutect2
- HECW2 | c.3303T>G p.R1101= | Silent (SNP) | VAF 110/448 reads (25%) | called by muse, varscan2
- HYI | c.153C>T p.A51= | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as rs1019716173; called by muse, mutect2
- KATNIP | c.354A>G p.L118= | Silent (SNP) | VAF 28/543 reads (5%) | called by muse, mutect2
- PDE6C | c.1966C>A p.R656= | Silent (SNP) | VAF 36/506 reads (7%) | catalogued as rs376438891, COSV101008524; called by muse, mutect2
- PNOC | c.417G>A p.S139= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- POTEE | c.2328C>T p.I776= | Silent (SNP) | VAF 149/816 reads (18%) | catalogued as COSV58250660; called by muse, mutect2, varscan2
- RELN | c.3198G>A p.P1066= | Silent (SNP) | VAF 88/894 reads (10%) | catalogued as rs767180170, COSV100634141; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNE4 | c.1095C>T p.L365= | Silent (SNP) | VAF 46/206 reads (22%) | called by muse, varscan2
- TENT5C | c.147G>A p.K49= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- GABRE | c.57-887A>G | Intron (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- KHDC3L | c.-14G>T | 5'UTR (SNP) | VAF 24/156 reads (15%) | catalogued as COSV64869022; called by muse, mutect2, varscan2
- KLRC3 | c.*48G>A | 3'UTR (SNP) | VAF 44/494 reads (9%) | called by muse, mutect2
- MSL3 | c.102+336G>A | Intron (SNP) | VAF 34/436 reads (8%) | called by muse, mutect2
- OR2M1P | n.753C>T | RNA (SNP) | VAF 36/638 reads (6%) | called by muse, mutect2
- PRAC1 | c.-3G>A | 5'UTR (SNP) | VAF 33/318 reads (10%) | catalogued as rs774958586; called by muse, mutect2, varscan2
- TDH | chr8:11347438 T>C | 5'Flank (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- UQCRB | c.*1431G>A | 3'UTR (SNP) | VAF 32/457 reads (7%) | called by muse, mutect2
- XAGE5 | c.*2C>A | 3'UTR (SNP) | VAF 28/464 reads (6%) | called by muse, mutect2
